Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4863, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4863-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Ad
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date:
Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

***** Added Report *****

TCGA-CZ-4863

PATHOLOGIC DIAGNOSIS:

A. SPECIMEN DESIGNATED "LEFT KIDNEY":

RENAL CELL CARCINOMA, clear cell type (7.5 cm), Fuhrman nuclear grade III/IV.

Tumor extends into the perinephric adipose tissue.

Tumor extends into renal vein (to within 2 cm of vein margin).

Renal vein, artery, and ureteric margins are negative for tumor.

AJCC Classification (6th Edition): T3b N0 MX.

The evaluation of this biopsy included PAS and trichrome stains.

B. SPECIMEN DESIGNATED "REGIONAL LYMPH NODES":

Eleven lymph nodes, no tumor present (0:11).

CLINICAL DATA:

History: [REDACTED] female with incidental renal mass left 9 x 6 cm enhancing

--> left hydro and 1 cm lymph node.

Operation: Left radical nephrectomy.

Clinical Diagnosis: L renal mass.

TISSUE SUBMITTED:

A/1) left kidney - #/s.

B/2) regional lymph nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patients name and unit number.

Part A is received fresh in the frozen section lab, labeled "#1 - L kidney", and consists of a left radical nephrectomy specimen (574 grams, 18.5 x 12.5 x 7 cm), to include left kidney (15 x 11 x 6.5 cm), ureter (6.5 cm in length x 0.6 cm in diameter), renal vein (1.4 cm in length x 0.8 cm in diameter), renal artery (1.6 cm in length x 0.4 cm in diameter), and a moderate amount of attached perinephric fat. Definitive Gerota's fascia is not identified. The outer surface is inked black and the specimen is bivalved, revealing a red/golden yellow, hemorrhagic, firm, fairly well circumscribed mass (7.5 x 6.5 x 6.1 cm) within the upper to mid-pole, focally protruding into the hilum, extending into the renal vein, coming to within 2 cm of the renal vein margin, 2.5 cm of the renal artery margin, and 7.9 cm of the ureteral margin. The mass grossly appears to invade the renal capsule but does not definitively extend through into the perinephric fat; as a result, coming to within 0.2 cm of the overlying black-inked soft tissue. The mass appears to extend into the renal sinus, focally impinging upon the renal pelvis and calyceal system. The renal parenchyma adjacent to the mass is focally pale tan and discolored. The corticomedullary junction is well-defined. Representative sections of the mass (T1A - T1C) are submitted to the Tissue Bank for special studies. Adjacent sections of tissue (corresponding to T1A - T1C) are submitted for quick fix. Representative sections of the mass are submitted for cytogenetics, as well as normal cortex, which are submitted for electron microscopy and immunofluorescence. Photographs are taken. No lymph nodes are identified within the attached perinephric fat.

Micro A1: ureter, renal vein and renal artery margins (en face), 3 frags, [REDACTED].

Micro A2+A3: renal mass in relationship to renal vein, renal artery, and pelvis at hilum, 2 frags total, [REDACTED].

Micro A4: renal mass in relationship to pelvis/possible renal vein

[page 2 of 4]
Pathology Report

involvement, 1 frag, [REDACTED]
Micro A5-A7: renal mass at deep extension to include adjacent parenchyma
and renal sinus/hilar adipose tissue, 3 frags total, [REDACTED]
Micro A8: corticomedullary junction and pelvis, 1 frag, [REDACTED]
Micro A9: "quick fix T1A", 1 frag, [REDACTED]
Micro A10: "quick fix T1B", 1 frag, [REDACTED]
Micro A11: "quick fix T1C", 1 frag, [REDACTED]

Part B, labeled "#2 - regional lymph node", and consists of a portion of yellow lobulated adipose tissue (4.5 x 2.2 x 1.2 cm), within which multiple tan/pink rubbery lymph nodes (ranging from 0.4 cm up to 1.9 cm in greatest dimension):

Micro B1: five single whole lymph nodes, 5 frags [REDACTED]
Micro B2: two single whole lymph nodes, 2 frags, [REDACTED]
Micro B3: three single whole lymph nodes, 3 frags [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:
LEFT KIDNEY, NEPHRECTOMY:

MILD CHRONIC CHANGES OF THE KIDNEY, WITH:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (1.2% OF GLOMERULI);
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (LESS THAN 2% OF THE PARENCHYMA);
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MILD.

FOCAL CORTICAL SCAR, MOST LIKELY SECONDARY TO CHRONIC TUMOR-RELATED VASCULAR COMPROMISE (SEE NOTE)

NOTE:

The sample of tissue chosen for evaluation of the kidney shows an area of focal cortical atrophy and scarring, most likely the result of chronic vascular compression by the large ipsilateral tumor. Features of obstructive uropathy are not seen at this time despite the mild degree of hydronephrosis. The remainder of the kidney parenchyma shows minimal chronic changes, within the expected range for a [REDACTED] woman. There is minimal focal global glomerulosclerosis (1.2% of glomeruli), minimal tubular atrophy and interstitial fibrosis (less than 2% of the parenchyma), and a mild degree of vascular sclerosis.

The kidney parenchyma has been reviewed by Dr. [REDACTED], Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A8) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 333 glomeruli present, of which 4 (1.2%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas but are diffusely hypoperfused. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. Less than 2% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries exhibit a mild degree of sclerosis.

The kidney cortex was also evaluated in block A7 (HE). This sample comes from an area of the kidney close to the tumor. There is prominent glomerulosclerosis and signs of hypoperfusion of glomeruli, a chronic

[page 3 of 4]
Pathology Report

interstitial inflammatory infiltrate, scattered tubular distention, and marked cortical atrophy. Overt vascular damage is not seen in the arterial vessel included in this sample.

[Clinical history: mild hydronephrosis, left renal mass]

Addendum #1 by

[page 4 of 4]
Pathology Report

Accession Number:

Report Status: Final

Type: Cytogenetics

CASE:

PATIENT:

Cytogeneticist:

KARYOTYPE: See below

METAPHASES COUNTED: 0

ANALYZED: 0

SCORED: 0

BANDING: GTG

INTERPRETATION:

No metaphases were available from this specimen, therefore the cytogenetic analysis could not be performed.

INDICATION FOR TEST:

? Kidney tumor

Source: NCI Genomic Data Commons file 458b6e7b-affc-4e61-8901-f7a1cc4d2f81 (TCGA-CZ-4863.700727C1-BD04-4753-ADB9-308B05C29A45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).